Somatic mutation profile of tumor specimen MBCProject_1037_T1_WES (aliquot MBCProject_1037_T1_WES_1) from CMI case MBCProject_1037, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 43.6 years (15,911 days).
Specimen MBCProject_1037_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bac936c8-ee9d-4bb8-9bb5-a7ee537aecc8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_1037_SALIVA (Saliva), aliquot MBCProject_1037_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f918259-b90c-4245-8e82-9b1c11564719

The open-access MAF lists 36 somatic variants for this specimen: 22 protein-altering or splice-affecting, 10 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 10, Nonsense Mutation 3, Intron 3, Splice Site 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.527G>A p.C176Y | Missense Mutation (SNP) | VAF 23/36 reads (64%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCF1 | c.229C>T p.R77* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as rs1561786344, COSV58228142; called by muse, mutect2
- CD93 | c.77C>T p.T26M | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs368421659; called by mutect2, varscan2
- CFAP44 | c.4666C>T p.R1556* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as rs749384603; called by mutect2, varscan2
- CRACD | c.1918C>T p.R640* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as rs1408300514; called by muse, mutect2
- CROCC | c.1402G>A p.V468I | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV65011767; called by muse, varscan2
- JAG1 | c.1348+1G>T p.X450_splice | Splice Site (SNP) | VAF 3/20 reads (15%) | catalogued as CS146066; called by muse, mutect2
- MACF1 | c.20363C>T p.T6788M (on ENST00000372915; = p.T4833M on NM_012090.5) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | catalogued as rs180745507, COSV57124625; called by mutect2, varscan2
- PCDHB8 | c.1082C>T p.A361V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.212); catalogued as rs781814454, COSV50754565; called by muse, varscan2
- RARA | c.907G>A p.G303S | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54190838; called by muse, mutect2, varscan2
- TGM6 | c.1409G>A p.R470K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.027); catalogued as COSV52477296, COSV52477602; called by muse, mutect2, varscan2
- CEP131 | c.2458G>A p.E820K (on ENST00000269392 / NM_001319228.2; = p.E817K on NM_014984.4) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- FAT3 | c.12679C>T p.P4227S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- HMCN1 | c.941T>G p.L314R | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- INHBE | c.776T>C p.L259P | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ITGB4 | c.232G>T p.V78L | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.022); called by mutect2, varscan2
- KANSL1L | c.1667T>G p.M556R | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- PLCD4 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- PREX2 | c.11A>C p.D4A | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PTGIR | c.365G>T p.S122I | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TRIOBP | c.3744_3780del p.S1248Rfs*96 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | called by mutect2, pindel
- ZC3H18 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- AGRN | c.2463C>G p.L821= | Silent (SNP) | VAF 12/34 reads (35%) | called by muse, varscan2
- CELA2A | c.723C>T p.L241= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs372916211; called by muse, mutect2, varscan2
- ERMP1 | c.810G>A p.L270= | Silent (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2
- H2AC16 | c.213C>G p.A71= | Silent (SNP) | VAF 9/72 reads (13%) | called by muse, mutect2, varscan2
- IKZF1 | c.921G>A p.K307= | Silent (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- KCTD10 | c.297C>G p.P99= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs770635100; called by mutect2, varscan2
- NLRC5 | c.2274G>A p.V758= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as rs745319115, COSV99348215; called by mutect2, varscan2
- PLXNB2 | c.3804C>T p.H1268= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs532502882; called by muse, mutect2, varscan2
- SFRP5 | c.237C>T p.H79= | Silent (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- SYNE1 | c.7173C>T p.A2391= (on ENST00000367255 / NM_182961.4; = p.A2398= on NM_033071.3) | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs774341012, COSV55038620; called by muse, mutect2
- SPPL2B | c.956+641G>A | Intron (SNP) | VAF 6/19 reads (32%) | catalogued as rs891804892; called by muse, mutect2, varscan2
- SREBF1 | c.3214+43C>T | Intron (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- TFAP2A | c.51+19C>T | Intron (SNP) | VAF 6/43 reads (14%) | catalogued as rs1051306672, COSV100116710; called by muse, mutect2, varscan2
- USP27X | chrX:49878733 C>A | 5'Flank (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2
